Somatic mutation profile of tumor specimen PCProject_0501_T1_WES (aliquot PCProject_0501_T1_WES_1) from CMI case PCProject_0501, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.7 years (23,632 days).
Specimen PCProject_0501_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c507e08c-e37e-43b8-bad1-111724a99ecd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0501_SALIVA (DNA), aliquot PCProject_0501_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bfce0a3-f705-4e80-8d0d-80f49109a8bd

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Nonsense Mutation 4, Intron 3, RNA 2, In Frame Del 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2856C>A p.D952E | Missense Mutation (SNP) | VAF 68/455 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV53971435; called by muse, mutect2, varscan2
- ADCY6 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 157/595 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57170135, COSV57171517; called by muse, mutect2, varscan2
- ARHGAP25 | c.1340G>A p.R447Q (on ENST00000409202 / NM_001007231.3; = p.R439Q on NM_014882.3) | Missense Mutation (SNP) | VAF 145/860 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.902); catalogued as rs200609383; called by muse, mutect2, varscan2
- BCL2L11 | c.526G>A p.E176K (on ENST00000393256 / NM_138621.5; = p.E116K on NM_006538.5) | Missense Mutation (SNP) | VAF 59/539 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.054); catalogued as rs1170116948, COSV58029750; called by muse, mutect2, varscan2
- BSN | c.7687C>T p.R2563W | Missense Mutation (SNP) | VAF 118/559 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs756867032, COSV99609332; called by muse, mutect2, varscan2
- CCDC120 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557081618; called by muse, mutect2, varscan2
- CDH4 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 154/912 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs202235537, COSV64656836; called by muse, mutect2, varscan2
- CDK19 | c.629A>C p.H210P | Missense Mutation (SNP) | VAF 62/516 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV60449825; called by muse, mutect2, varscan2
- FLRT3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99428631; called by muse, mutect2, varscan2
- GDNF | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 99/499 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1478023030, COSV58479222; called by muse, mutect2, varscan2
- IRX6 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 137/689 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs886809200; called by muse, mutect2, varscan2
- MAP4K1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 47/493 reads (10%) | catalogued as rs745506984, COSV67711110, COSV67711312; called by muse, mutect2
- METTL22 | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 135/835 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1463049249; called by muse, mutect2, varscan2
- MFAP4 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 90/465 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs142104942; called by muse, mutect2, varscan2
- OBSCN | c.9419G>A p.R3140Q | Missense Mutation (SNP) | VAF 276/757 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs200257680, COSV99478094; called by muse, mutect2, varscan2
- PKHD1L1 | c.9206del p.M3069Sfs*13 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | catalogued as COSV65741083; called by mutect2, pindel
- SH3BGR | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 70/527 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs143613589; called by muse, mutect2, varscan2
- ST3GAL3 | c.1105C>T p.R369* (on ENST00000361392 / NM_174964.4; = p.R354* on NM_006279.5) | Nonsense Mutation (SNP) | VAF 207/1205 reads (17%) | catalogued as rs758301958, COSV53512663; called by muse, mutect2, varscan2
- TOPBP1 | c.2180C>T p.T727M | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as rs759938150, COSV53438107; called by muse, mutect2
- ZNF142 | c.3709C>T p.R1237W (on ENST00000411696 / NM_001379660.1; = p.R1037W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/732 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373357666; called by muse, mutect2, varscan2
- ACAP2 | c.1488A>G p.R496= | Splice Region (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2
- DPP9 | c.1373C>T p.T458I (on ENST00000598800; = p.T487I on NM_139159.5) | Missense Mutation (SNP) | VAF 147/816 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- HERPUD1 | c.173_175del p.Y58del | In Frame Del (DEL) | VAF 22/266 reads (8%) | called by mutect2, pindel
- ILDR2 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- METTL16 | c.403_406dup p.D136Gfs*2 | Nonsense Mutation (INS) | VAF 32/322 reads (10%) | called by mutect2, pindel, varscan2
- NGF | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- NIN | c.66_74del p.T23_T25del | In Frame Del (DEL) | VAF 82/845 reads (10%) | called by mutect2, pindel
- PTPRT | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 73/515 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM39 | c.1184T>C p.F395S | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAXO1 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 101/686 reads (15%) | called by muse, mutect2, varscan2
- UROD | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 107/894 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ADAMTS20 | c.741A>G p.R247= | Silent (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- AGXT2 | c.1116G>A p.A372= | Silent (SNP) | VAF 116/915 reads (13%) | catalogued as rs1207970057, COSV51485094; called by muse, mutect2, varscan2
- CARS1 | c.468G>A p.Q156= | Silent (SNP) | VAF 72/489 reads (15%) | called by muse, mutect2, varscan2
- ESPNL | c.543G>A p.E181= | Silent (SNP) | VAF 112/454 reads (25%) | called by muse, mutect2, varscan2
- FAM171B | c.81C>T p.P27= | Silent (SNP) | VAF 198/1213 reads (16%) | called by muse, mutect2, varscan2
- MED23 | c.2961A>C p.L987= | Silent (SNP) | VAF 32/246 reads (13%) | called by muse, varscan2
- PTPRM | c.1401G>T p.R467= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as COSV59875103; called by muse, mutect2, varscan2
- RALGAPB | c.4221A>G p.Q1407= | Silent (SNP) | VAF 28/251 reads (11%) | called by muse, mutect2, varscan2
- VPS52 | c.1185C>T p.R395= | Silent (SNP) | VAF 34/274 reads (12%) | catalogued as rs184438144, COSV101460476; called by muse, mutect2, varscan2
- AC064807.1 | n.926G>A | RNA (SNP) | VAF 120/624 reads (19%) | called by muse, mutect2, varscan2
- FGFR1 | c.92-10401C>T | Intron (SNP) | VAF 57/413 reads (14%) | catalogued as rs778168231, COSV58341272; called by muse, mutect2, varscan2
- KITLG | c.15+39G>A | Intron (SNP) | VAF 252/756 reads (33%) | called by muse, varscan2
- NDUFS7 | c.228+590C>A | Intron (SNP) | VAF 80/370 reads (22%) | called by muse, mutect2, varscan2
- SVIL2P | n.1902G>A | RNA (SNP) | VAF 164/995 reads (16%) | called by muse, mutect2, varscan2
